Somatic mutation profile of tumor specimen TCGA-VQ-A91Y-01A (aliquot TCGA-VQ-A91Y-01A-11D-A410-08) from TCGA case TCGA-VQ-A91Y, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.8 years (24,774 days).
Specimen TCGA-VQ-A91Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe5c9151-9a84-4211-a696-c9190ef90da7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A91Y-10A (Blood Derived Normal), aliquot TCGA-VQ-A91Y-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d11d67cf-b895-4a52-ba2d-8ae6ce2e0519

The open-access MAF lists 48 somatic variants for this specimen: 39 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 8, Nonsense Mutation 4, Splice Region 1, Splice Site 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.8407G>A p.D2803N | Missense Mutation (SNP) | VAF 173/746 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs777802496, COSV100316475, COSV60915238; called by muse, mutect2, varscan2
- ANO4 | c.1007T>C p.L336S (on ENST00000392977 / NM_001286615.2; = p.L301S on NM_178826.4) | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100152398; called by muse, mutect2, varscan2
- BICC1 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV65860201; called by muse, mutect2
- CHD5 | c.2110C>T p.Q704* | Nonsense Mutation (SNP) | VAF 24/114 reads (21%) | catalogued as COSV99312979; called by muse, mutect2, varscan2
- CR1 | c.3299G>C p.R1100T | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs769092015, COSV100887466; called by muse, mutect2, varscan2
- CRHR2 | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs140591778; called by muse, mutect2, varscan2
- CRX | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1313125094, COSV99704327; called by muse, mutect2, varscan2
- DLGAP4 | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765878319, COSV59423712; called by muse, mutect2, varscan2
- EPSTI1 | c.745C>T p.Q249* (on ENST00000398762 / NM_001330543.2; = p.Q238* on NM_033255.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 101/506 reads (20%) | catalogued as COSV100552730; called by muse, mutect2, varscan2
- ERG | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.09); catalogued as rs552037654, COSV55726607; called by muse, mutect2, varscan2
- HERC6 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs902456813, COSV52028152; called by muse, mutect2
- HTR7 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99519229; called by muse, mutect2, varscan2
- KL | c.451A>T p.I151F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); catalogued as COSV101199048; called by muse, mutect2, varscan2
- MTUS1 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.015); catalogued as COSV100029224; called by muse, mutect2, varscan2
- NDUFAF6 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV99712650; called by muse, mutect2, varscan2
- OR8I2 | c.763A>T p.I255F | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as COSV100135944; called by muse, mutect2, varscan2
- PAPOLA | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV99354034; called by muse, mutect2, varscan2
- PCDHA13 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as COSV56513485; called by muse, mutect2, varscan2
- PID1 | c.606C>A p.C202* (on ENST00000354069 / NM_001330156.1; = p.C200* on NM_017933.5) | Nonsense Mutation (SNP) | VAF 40/167 reads (24%) | catalogued as COSV100819583, COSV62478051; called by muse, mutect2, varscan2
- PKHD1L1 | c.6760T>C p.S2254P | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV101005749; called by muse, mutect2, varscan2
- PLP1 | c.688A>G p.T230A | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV100393329; called by muse, mutect2
- RBPJ | c.572A>C p.N191T | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100623559; called by muse, mutect2, varscan2
- RC3H1 | c.3256G>A p.V1086I | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.956); catalogued as rs1486936389, COSV99281161; called by muse, mutect2, varscan2
- RNF17 | c.3059C>T p.T1020I | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.983); catalogued as rs780445922, COSV99692598; called by muse, mutect2, varscan2
- SGPL1 | c.571A>C p.I191L | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV100167270; called by muse, mutect2, varscan2
- SLC26A7 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1193114782, COSV52594013, COSV52605870; called by muse, mutect2, varscan2
- SLC6A16 | c.891G>T p.L297F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV100242623; called by muse, varscan2
- SPTB | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101072017; called by muse, mutect2, varscan2
- ST8SIA1 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as rs755554035, COSV53952717; called by muse, mutect2, varscan2
- SUN3 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as COSV99813933; called by muse, mutect2
- TCN1 | c.1199C>G p.T400S | Missense Mutation (SNP) | VAF 39/362 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV99953160; called by muse, mutect2, varscan2
- TMEM131L | c.3317C>A p.P1106Q | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); catalogued as COSV99547050; called by muse, mutect2
- TMEM211 | c.446G>A p.R149Q (on ENST00000423535; = p.R78Q on NM_001001663.3) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756214220, COSV101236036; called by muse, mutect2, varscan2
- TP53 | c.684C>G p.D228E | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV52662095, COSV52662428, COSV52675830, COSV52864128; called by muse, varscan2
- TPO | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs201782331; called by muse, mutect2, varscan2
- TRHDE | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.33); catalogued as COSV53830330, COSV99669845; called by muse, mutect2, varscan2
- ZMIZ1 | c.2019C>T p.C673= | Splice Region (SNP) | VAF 15/65 reads (23%) | catalogued as rs766542380, COSV100565992; called by muse, mutect2, varscan2
- MUC6 | c.3383-29_3387del p.X1128_splice | Splice Site (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel
- TMEM30B | c.831_844del p.G281Qfs*108 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | called by mutect2, pindel, varscan2
- ARHGAP11A | c.2545T>C p.L849= | Silent (SNP) | VAF 41/177 reads (23%) | catalogued as COSV100276721; called by muse, mutect2, varscan2
- FBN2 | c.8136C>T p.N2712= | Silent (SNP) | VAF 39/202 reads (19%) | catalogued as COSV99325938; called by muse, mutect2, varscan2
- FSTL4 | c.378C>T p.T126= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs767881494, COSV99531858, COSV99532849; called by muse, mutect2, varscan2
- MARK2 | c.1887G>A p.G629= (on ENST00000402010 / NM_001039469.2; = p.G574= on NM_004954.5) | Silent (SNP) | VAF 44/262 reads (17%) | catalogued as rs745421643, COSV100158282; called by muse, mutect2, varscan2
- MYH6 | c.2592G>A p.T864= | Silent (SNP) | VAF 41/161 reads (25%) | catalogued as rs752148935, COSV100676393; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEUROD6 | c.303G>A p.A101= | Silent (SNP) | VAF 44/285 reads (15%) | catalogued as rs201334652, COSV99773948; called by muse, mutect2, varscan2
- NRG1 | c.1071C>T p.N357= (on ENST00000405005 / NM_013964.5; = p.N362= on NM_013956.5) | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as rs114135581, COSV99828039; called by muse, mutect2, varscan2
- TSHZ3 | c.2022G>A p.P674= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs151270303; called by muse, mutect2, varscan2
- AP001042.1 | n.2336T>A | RNA (SNP) | VAF 22/190 reads (12%) | called by muse, mutect2, varscan2
